Somatic mutation profile of tumor specimen ALCH-B1P2-TTP1-A (aliquot ALCH-B1P2-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1P2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.5 years (26,844 days).
Specimen ALCH-B1P2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a9c1310-aeda-4a51-95d4-18fb3806f6b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1P2-NB1-A (Blood Derived Normal), aliquot ALCH-B1P2-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/320b6ee5-4ac2-456f-ba18-430a68739cb2

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 15, Intron 4, Splice Site 2, In Frame Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 29/249 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- CXCR1 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55281473; called by muse, mutect2
- FMR1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99502848, COSV99502862; called by muse, mutect2
- HOMEZ | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs776204768, COSV62537517; called by muse, mutect2, varscan2
- MYH7 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV62518301; called by muse, mutect2, varscan2
- OR14A16 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as COSV100713775, COSV62926438; called by muse, mutect2, varscan2
- PAX4 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs151008936; called by muse, mutect2, varscan2
- PDGFRA | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 47/350 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV57265192; called by muse, mutect2, varscan2
- PRDM6 | c.1031C>G p.S344W | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68334874; called by muse, mutect2
- SBNO2 | c.4031G>A p.G1344D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.093); catalogued as rs1457729543; called by muse, mutect2, varscan2
- SEMA6B | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1382019875; called by mutect2, varscan2
- SVEP1 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.343); catalogued as rs760547627; called by muse, mutect2, varscan2
- TRIM67 | c.774_779del p.P259_P260del | In Frame Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs746097685; called by mutect2, varscan2
- ABRA | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- CD34 | c.356C>G p.T119R | Missense Mutation (SNP) | VAF 109/470 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CIC | c.3721C>A p.P1241T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by mutect2, varscan2
- CLASP2 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CP | c.1194A>T p.L398F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSMD1 | c.9910C>T p.H3304Y (on ENST00000520002; = p.H3303Y on NM_033225.6) | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DNAH8 | c.3899G>T p.W1300L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DND1 | c.605-1G>T p.X202_splice | Splice Site (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- DSP | c.4351C>A p.L1451M | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- GOLGA4 | c.4319A>C p.N1440T | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HFM1 | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.438); called by muse, mutect2
- KIF3B | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMB2 | c.2972A>C p.N991T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- LMF2 | c.2103G>T p.R701S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NEB | c.15956C>A p.P5319Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE8B | c.1016A>G p.K339R | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- TAF1 | c.1240G>T p.A414S (on ENST00000373790 / NM_138923.4; = p.A435S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- TCF25 | c.1857_1872+1del p.X619_splice | Splice Site (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel
- TF | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UTP20 | c.1727A>T p.E576V | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- XRCC1 | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ABRA | c.78C>T p.V26= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- CEMIP | c.2961C>A p.I987= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99587416; called by muse, mutect2
- HMCN1 | c.16473C>T p.N5491= | Silent (SNP) | VAF 23/296 reads (8%) | called by muse, mutect2
- ICE1 | c.3057C>T p.T1019= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as COSV56832316; called by muse, mutect2, varscan2
- ITIH6 | c.2268C>G p.S756= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- KALRN | c.2211C>A p.I737= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as COSV53758124; called by muse, mutect2, varscan2
- KCNMA1 | c.3567G>T p.L1189= (on ENST00000286628 / NM_001161352.2; = p.L1131= on NM_002247.4) | Silent (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- MASP1 | c.1416G>A p.Q472= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV56224539; called by muse, mutect2, varscan2
- OR5D14 | c.861G>T p.L287= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as COSV100162192; called by muse, mutect2, varscan2
- PAQR9 | c.813C>A p.P271= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs769366560; called by muse, mutect2, varscan2
- RNF112 | c.366G>A p.L122= | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- SERPINA7 | c.264C>A p.T88= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- SLC5A7 | c.1503A>G p.L501= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as rs921978446; called by muse, mutect2, varscan2
- UNC13A | c.2317C>A p.R773= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV53201796; called by muse, mutect2
- WDSUB1 | c.1164G>A p.R388= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, varscan2
- AC022182.2 | n.134C>A | RNA (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- CBR1 | c.398-199C>T | Intron (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2, varscan2
- FASN | c.7147-49G>T | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- RHBG | c.1235-58A>T | Intron (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- SFTPC | c.324+25_324+39del | Intron (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel
